Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD8-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC in Segment 4

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JW 5/19/14

Specimen : Liver lateral segment

Gross Photo

GROSS:

Specimen:

Liver: 21.5 x 11.5 x 3.0 cm, 281.5 gm (fresh)

Gallbladder: 7.0 cm in length, 4.0 cm in diameter (fresh)

Operation: Lateral segmentectomy

Lesion: A well-defined mass

Size: 1.5 x 1.8 x 2.0 cm

Cut surface: Yellowish tan, and granular

Gross type

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 3.5 cm)

Satellite nodule: No

Remaining parenchyma: Unremarkable

Portal vein invasion: No

Representative sections are submitted

Gross photo: Present

Blocks

T1-4, TB, bile tinged mass and surrounding liver parenchyme x 5

L, NB, nontumorous liver parenchyme x 2

RM, resection margin of liver x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma:

(Edmondson-Steiner grade)

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (10 %)

Fibrous capsule formation: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: No

[page 2 of 2]
Non-tumor liver pathology

1. Chronic hepatitis: Yes
- 1-1. Etiology: HCV
- 1-2. Grade, lobular: Mild
- 1-3. Grade, portoperiportal: Moderate
- 1-4. Stage (fibrosis): Periportal
- 1-5. Cirrhosis: No
2. Dysplastic nodule: No
3. Ductal epithelial dysplasia: No
4. Other liver diseases: No

NOT reported. Gross:

cervix, senile atrophy

cervix, smear, inflammation

cervix, smear, senile atrophy

Anus, ectomy, hemorrhoid

liver, ectomy, hepatocellular carcinoma

T56000, P10, M81703

gallbladder, ectomy, chronic cholecystitis, cholelithiasis

T57000, P10, M43005, M30011

DIAGNOSIS:

Liver, segment 4, lateral segmentectomy:

Hepatocellular carcinoma

Gallbladder, cholecystectomy:

Chronic cholecystitis

Cholelithiasis

Suggestion :

Source: NCI Genomic Data Commons file d8cd4678-7151-48d5-8680-5e6b910f8d9d (TCGA-DD-AAD8.5536ED7C-6CC3-442D-A8FD-5EE91C98F358.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).